Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7784, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7784-01A (Primary Tumor).

Collection Date: [REDACTED]

PATIENT HISTORY:

The patient is a [REDACTED]-year-old [REDACTED] male with a history of PSA value of 4.1. The patient also has a history of biopsy on [REDACTED] this biopsy reveals: Poorly differentiated prostatic adenocarcinoma Gleason score 3+4 = 7 in the right apex. The patient also has a history of appendectomy, mild COPD, stenosis in cervical spine, and high blood pressure.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN NINE LYMPH NODES (0/9).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN FOUR LYMPH NODES (0/4).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT SIDES OF PROSTATE AND HAS A GREATEST NODULAR DIAMETER OF 2.0 CM.
- C. CARCINOMA INVOLVES APPROXIMATELY 8% OF THE EXAMINED PROSTATE BY VOLUME.
- D. THE TUMOR IS ORGAN-CONFINED AND SHOWS NO EVIDENCE OF EXTRAPROSTATIC EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. MULTIFOCAL PERINEURAL INVASION IS PRESENT.
- H. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS PRESENT.
- J. PATHOLOGIC TNM STAGE: pT2c N0.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 4.1
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	40.2gm
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	13
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 515f6b91-d040-4f45-b238-6dcf557e58ad (TCGA-EJ-7784.D140C74D-8E74-43DA-A181-63A7BBE718AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).